Gene-level copy-number profile of tumor specimen TCGA-14-1795-01A from TCGA case TCGA-14-1795, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 66.7 years (24,375 days).
Specimen TCGA-14-1795-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.a5536e80-6a52-4326-be30-f68cb59aa8ce.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-14-1795-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/717a4b83-8d40-4687-ade6-2454d0929291

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 44; copy number 1: 4,847; copy number 2: 51,915; copy number 3: 2,997; copy number 16: 17.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-14-1795-01A-01D-0591-01): tumor purity 0.68, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 44 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:50,780,340–51,060,103, 5 genes: PHBP12, MRPS6P2, CDKN2C, MIR4421, MIR6500.
- chr1:51,107,222–51,107,331, 1 gene: Y_RNA.
- chr9:21,278,050–22,455,740, 38 genes: IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 17 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:116,672,196–116,954,334, 8 genes, copy number 16 (within-gene range 3–16): MET, CAPZA2, AC002543.1, Y_RNA, RNA5SP239, ST7-AS1, AC106873.5, AC106873.7.
- chr7:116,953,899–117,119,719, 9 genes, copy number 16 (within-gene range 3–16): ST7-OT4, AC106873.8, AC106873.3, AC106873.2, AC106873.6, AC106873.4, AC106873.1, TPM3P1, MIR6132.

Autosomal genes at a single copy (total copy number 1): 2,467. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
